Somatic mutation profile of tumor specimen TCGA-DK-A3IN-01A (aliquot TCGA-DK-A3IN-01A-11D-A20D-08) from TCGA case TCGA-DK-A3IN, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.7 years (26,562 days).
Specimen TCGA-DK-A3IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19da9a2d-6aea-4826-9fb1-ed30322e7211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3IN-10A (Blood Derived Normal), aliquot TCGA-DK-A3IN-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2bd3b33-d8e5-4d67-8be7-de2e3a7df34a

The open-access MAF lists 425 somatic variants for this specimen: 301 protein-altering or splice-affecting, 111 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 261, Silent 111, Nonsense Mutation 20, Intron 8, Frame Shift Del 7, Splice Region 6, Splice Site 5, 5'UTR 3, Frame Shift Ins 1, 3'UTR 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA1 | c.5773C>T p.R1925W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs568280586, COSV66068709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.10454C>T p.S3485L | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV71294320; called by muse, mutect2, varscan2
- ABCA5 | c.2476C>G p.L826V | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV67019098; called by muse, mutect2, varscan2
- ABCC1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as rs775434031, COSV60691421; called by muse, mutect2, varscan2
- ACOXL | c.686A>G p.N229S | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.105); catalogued as COSV61330751; called by muse, mutect2, varscan2
- ADAMTS18 | c.3347C>G p.P1116R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV51398236, COSV51423100; called by muse, mutect2, varscan2
- ADAMTS18 | c.2944C>G p.Q982E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV51423107; called by muse, mutect2, varscan2
- ADAMTS9 | c.5735T>C p.V1912A | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV55790551; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2924G>A p.R975K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs761443595, COSV65900222; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV58446962; called by muse, mutect2, varscan2
- ADH6 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52958195; called by muse, mutect2, varscan2
- ANK3 | c.6042G>C p.E2014D | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs764006864, COSV55081925; called by muse, mutect2, varscan2
- ANKIB1 | c.2689G>C p.D897H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56066093; called by muse, mutect2
- ARAP2 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); catalogued as COSV58292146; called by muse, mutect2, varscan2
- ARHGAP11B | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as COSV70288489; called by muse, mutect2, varscan2
- ARHGAP15 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV54520983; called by muse, mutect2, varscan2
- ARID1A | c.2999C>T p.S1000F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61376095, COSV61380392, COSV61383336; called by muse, mutect2, varscan2
- ARID1A | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as COSV61379484; called by muse, mutect2, varscan2
- ARMCX5 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55767651; called by muse, mutect2, varscan2
- ARNTL2 | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV53829004; called by muse, mutect2, varscan2
- ASAP2 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV55638678; called by muse, mutect2, varscan2
- ATG13 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.632); catalogued as COSV56322135; called by muse, mutect2, varscan2
- ATP11B | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60029122; called by muse, mutect2, varscan2
- BFSP2 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV56591943; called by muse, mutect2, varscan2
- BPIFB3 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64957656; called by muse, mutect2
- BRI3BP | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58297423; called by muse, mutect2, varscan2
- BTN3A3 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV55073819; called by muse, mutect2, varscan2
- C16orf72 | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 463/571 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59917132; called by muse, mutect2, varscan2
- C1orf127 | c.1291-1G>A p.X431_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as COSV65438947; called by muse, mutect2, varscan2
- C2CD5 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV61727677; called by muse, mutect2, varscan2
- C2orf78 | c.1824G>C p.K608N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1385260571, COSV68519412; called by muse, mutect2, varscan2
- CACNA1A | c.5458G>C p.E1820Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV64212402; called by muse, mutect2, varscan2
- CADM2 | c.818G>A p.R273Q (on ENST00000407528 / NM_001167674.2; = p.R275Q on NM_153184.4) | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV67366748; called by muse, mutect2, varscan2
- CALCRL | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66477458; called by muse, mutect2, varscan2
- CAPN3 | c.2465G>C p.*822Sext*62 | Nonstop Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as CM148800; called by muse, mutect2, varscan2
- CAPRIN1 | c.1564A>G p.M522V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.99); PolyPhen benign (0.203); catalogued as COSV58222248; called by muse, mutect2, varscan2
- CASP8 | c.1015C>T p.Q339* (on ENST00000432109 / NM_033355.3; = p.Q356* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 45/166 reads (27%) | catalogued as COSV51852083; called by muse, mutect2, varscan2
- CC2D2A | c.4630G>C p.D1544H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58013835; called by muse, mutect2, varscan2
- CCDC43 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 25/137 reads (18%) | catalogued as COSV59519933; called by muse, mutect2, varscan2
- CCL1 | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV56774669, COSV56775699; called by muse, varscan2
- CCL1 | c.105C>G p.F35L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV56775708; called by muse, varscan2
- CCR8 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV58337999; called by muse, varscan2
- CDH18 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV56960859; called by muse, mutect2
- CDKN1A | c.247dup p.R83Pfs*6 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as COSV55190096; called by mutect2, pindel
- CDNF | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV65805700, COSV65805971, COSV65806275; called by muse, mutect2, varscan2
- CEBPZ | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.502); catalogued as COSV52208467; called by muse, mutect2, varscan2
- CFAP221 | c.2428C>G p.Q810E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV54662645; called by muse, mutect2, varscan2
- CFAP410 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.084); catalogued as COSV57395452; called by muse, mutect2, varscan2
- CHMP2A | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53398216; called by muse, mutect2, varscan2
- CIT | c.2884G>A p.E962K | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV55883134; called by muse, mutect2, varscan2
- CLEC1B | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV53725842, COSV53726651; called by muse, mutect2, varscan2
- COL1A2 | c.3358G>C p.D1120H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51966131; called by muse, mutect2, varscan2
- COL1A2 | c.3907G>A p.E1303K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1289686179, COSV51966141; called by muse, mutect2, varscan2
- COL4A2 | c.3934G>T p.D1312Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV64634129; called by muse, mutect2
- COPB2 | c.1463T>C p.L488P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60813861; called by muse, mutect2, varscan2
- CRACD | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV51731408; called by muse, mutect2, varscan2
- CRYZL1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV51679873; called by muse, mutect2, varscan2
- CYP2F1 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs142026539; called by muse, mutect2, varscan2
- CYP3A4 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199908125, COSV60500893; called by muse, mutect2, varscan2
- CYP4F2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV50002852; called by muse, mutect2
- DAZAP2 | c.135C>T p.L45= | Splice Region (SNP) | VAF 20/104 reads (19%) | catalogued as COSV66313273; called by muse, varscan2
- DBI | c.169G>A p.D57N (on ENST00000355857 / NM_001079862.3; = p.D74N on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as rs972363812, COSV58348234; called by muse, mutect2, varscan2
- DLL1 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs1409058694, COSV64538807; called by muse, mutect2, varscan2
- DNAH1 | c.11006C>G p.S3669C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV70236233; called by muse, mutect2, varscan2
- DNAH3 | c.3179A>T p.K1060I | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54551444; called by muse, varscan2
- DNAH7 | c.10020C>G p.F3340L | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.912); catalogued as COSV100416134, COSV56786297; called by muse, mutect2, varscan2
- DNAI2 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV56762488; called by muse, mutect2
- DOK4 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555516093, COSV54674341; called by muse, mutect2, varscan2
- DRAM2 | c.129C>T p.I43= | Splice Region (SNP) | VAF 19/95 reads (20%) | catalogued as rs1222569944, COSV54416434; called by muse, mutect2, varscan2
- DTNB | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111695014, COSV56484687; called by muse, mutect2
- DTNBP1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV59037464, COSV59043932; called by muse, mutect2, varscan2
- EAPP | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV51653236; called by muse, mutect2, varscan2
- EDEM3 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV58923215, COSV58927967; called by muse, mutect2, varscan2
- ELAVL2 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV56370850; called by muse, mutect2, varscan2
- ELOA2 | c.1087T>A p.S363T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV55308540; called by muse, mutect2
- EPB41 | c.475C>G p.Q159E | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV58054114; called by muse, varscan2
- EPB41 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58054133; called by muse, varscan2
- EPB41L1 | c.1817C>G p.S606C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52444691; called by muse, mutect2, varscan2
- EPHB2 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65866780; called by muse, mutect2, varscan2
- ERBB3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV57247555, COSV57258332; called by muse, mutect2, varscan2
- ESX1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV65425148; called by muse, mutect2, varscan2
- FAM111B | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV59113663; called by muse, mutect2, varscan2
- FAM120C | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV60259212, COSV60262491; called by muse, mutect2, varscan2
- FAM135B | c.1984C>T p.H662Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.062); catalogued as COSV52753426; called by muse, mutect2, varscan2
- FAM135B | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV50525665, COSV50540409; called by muse, mutect2, varscan2
- FAM160A2 | c.1607G>A p.R536Q (on ENST00000449352 / NM_001098794.2; = p.R550Q on NM_032127.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as rs754164103, COSV56414767; called by muse, mutect2, varscan2
- FAP | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs750073479, COSV51867574; called by muse, mutect2, varscan2
- FAR1 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61386450; called by muse, mutect2, varscan2
- FBXW7 | c.1922C>G p.S641* (on ENST00000281708 / NM_001349798.2; = p.S561* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV55906561, COSV55910110; called by muse, mutect2, varscan2
- FCRL2 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.071); catalogued as COSV63838192; called by muse, mutect2, varscan2
- FEZF2 | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51863402, COSV51863642, COSV51864532; called by muse, mutect2, varscan2
- FGA | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV57400828; called by muse, mutect2, varscan2
- FMO3 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs113006768, COSV100882482, COSV63008614; called by muse, mutect2, varscan2
- FNDC7 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV54758039; called by muse, mutect2, varscan2
- FRMPD1 | c.4453G>C p.E1485Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs760505793, COSV66703113, COSV66703616; called by muse, mutect2, varscan2
- GAB4 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs751763320, COSV101271958, COSV68755234; called by muse, mutect2, varscan2
- GABRG1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV54961744; called by muse, mutect2, varscan2
- GBP1 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs370449948, COSV65084520; called by muse, mutect2, varscan2
- GCC2 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.863); catalogued as COSV59180081; called by muse, mutect2, varscan2
- GCC2 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV59180089; called by muse, mutect2, varscan2
- GCKR | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs376157442, COSV53111014; called by muse, mutect2, varscan2
- GIMAP8 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV56233884; called by muse, mutect2, varscan2
- GLI3 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV67894917; called by muse, mutect2, varscan2
- GLIPR1L1 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as rs1002715252, COSV56881740; called by muse, mutect2, varscan2
- GPATCH1 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV50126583; called by muse, mutect2, varscan2
- GRHL3 | c.1498G>C p.E500Q (on ENST00000350501 / NM_198174.3; = p.E505Q on NM_021180.3) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.198); catalogued as COSV52570973; called by muse, mutect2, varscan2
- HHIPL2 | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58567879; called by muse, mutect2, varscan2
- HHIPL2 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 93/344 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as COSV58564316, COSV58567891; called by muse, mutect2, varscan2
- HMGCS1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57291588; called by muse, mutect2, varscan2
- HNRNPK | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1243337115, COSV61091013; called by muse, mutect2, varscan2
- HOXA3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV57828926; called by muse, mutect2, varscan2
- HYDIN | c.8014G>C p.E2672Q | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV59270179; called by muse, mutect2, varscan2
- IL21 | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV52647223; called by muse, mutect2, varscan2
- INTS7 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65345528; called by muse, mutect2, varscan2
- INTS8 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.208); catalogued as rs1159011550, COSV58253356; called by muse, mutect2, varscan2
- INTS8 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 107/404 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58253364; called by muse, mutect2, varscan2
- IQCN | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.351); catalogued as COSV66577793; called by muse, mutect2, varscan2
- KALRN | c.5661+1G>A p.X1887_splice (on ENST00000360013 / NM_001024660.4; = p.X190_splice on NM_007064.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as COSV52264529; called by muse, mutect2, varscan2
- KCNA5 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52908723; called by muse, mutect2, varscan2
- KCNG4 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279382699, COSV57585968; called by muse, mutect2, varscan2
- KCNN1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV55842200; called by muse, mutect2, varscan2
- KIAA0100 | c.4830C>A p.H1610Q | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66496331; called by muse, mutect2
- KIF13A | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV52465659; called by muse, mutect2, varscan2
- KIF17 | c.1749G>C p.Q583H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV56122435; called by muse, mutect2, varscan2
- KIR2DL1 | c.870G>A p.E290= | Splice Region (SNP) | VAF 47/251 reads (19%) | catalogued as COSV52408750, COSV52415410; called by muse, mutect2, varscan2
- KPNA1 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV60271711; called by muse, mutect2, varscan2
- LAMA5 | c.6418G>C p.E2140Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as rs779553347, COSV53372482; called by muse, mutect2, varscan2
- LHX3 | c.455-1G>A p.X152_splice (on ENST00000371748 / NM_178138.6; = p.X157_splice on NM_014564.5) | Splice Site (SNP) | VAF 10/18 reads (56%) | catalogued as rs1430439163, COSV65583430; called by muse, mutect2, varscan2
- LILRA1 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1440947365, COSV52182869; called by muse, mutect2, varscan2
- LRRC31 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV52980637, COSV52983014; called by muse, mutect2, varscan2
- LRRIQ1 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV67813920; called by muse, mutect2, varscan2
- LRRK2 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752123862, COSV104406132, COSV54170440; called by muse, mutect2, varscan2
- LYN | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs779606369, COSV70205870; called by muse, mutect2, varscan2
- LYST | c.8857G>A p.E2953K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV67713996; called by muse, mutect2, varscan2
- MAN2A1 | c.3153G>C p.L1051F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV54856815; called by muse, mutect2, varscan2
- MARK4 | c.357G>A p.V119= | Splice Region (SNP) | VAF 43/154 reads (28%) | catalogued as COSV53468879; called by muse, mutect2, varscan2
- MBD5 | c.4216G>C p.E1406Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.719); catalogued as COSV68698938; called by muse, mutect2, varscan2
- MBLAC1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs768084664, COSV53542825, COSV53542932; called by muse, mutect2, varscan2
- MBTPS1 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV58572584; called by muse, mutect2, varscan2
- MCM4 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV50632655; called by muse, mutect2, varscan2
- MDH1 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51865110; called by muse, mutect2, varscan2
- MFSD8 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV56553011; called by muse, mutect2, varscan2
- MGAT1 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 23/63 reads (37%) | PolyPhen possibly damaging (0.67); catalogued as rs745639734, COSV57135456; called by muse, mutect2, varscan2
- MGAT1 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | PolyPhen probably damaging (0.974); catalogued as COSV57135466; called by muse, mutect2, varscan2
- MICAL1 | c.2151C>G p.F717L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV57807088; called by muse, mutect2, varscan2
- MME | c.819G>C p.M273I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as COSV64710794; called by muse, mutect2, varscan2
- MMP21 | c.1469C>G p.T490S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV61766250; called by muse, mutect2, varscan2
- MPP4 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100207375; called by mutect2, varscan2
- MRPS22 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1189110848, COSV60351253; called by muse, mutect2
- MYCBPAP | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV60412293; called by muse, mutect2
- MYH11 | c.5596G>A p.E1866K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs148743922, COSV55569720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.4394C>T p.S1465L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.228); catalogued as rs1033511138, CM115871, COSV62523799; called by muse, mutect2, varscan2
- MYT1L | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101217473, COSV67703614; called by muse, mutect2, varscan2
- NCOA1 | c.3945G>C p.M1315I | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV56052987; called by muse, mutect2, varscan2
- NDST4 | c.2284C>G p.Q762E | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52137354; called by muse, mutect2, varscan2
- NDUFB6 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV62118219; called by muse, mutect2, varscan2
- NECAB1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV70244256; called by muse, mutect2, varscan2
- NKTR | c.2405G>C p.R802T | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV51775292; called by muse, mutect2, varscan2
- NLRP2 | c.3000G>C p.K1000N | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV54760387; called by muse, mutect2, varscan2
- NME9 | c.562G>C p.E188Q (on ENST00000333911 / NM_001349024.2; = p.E127Q on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.398); catalogued as COSV58622655; called by muse, mutect2, varscan2
- OPTN | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as COSV53813211; called by muse, mutect2, varscan2
- OR2T11 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV58187291; called by muse, mutect2, varscan2
- PADI3 | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64935408; called by muse, mutect2
- PALLD | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.557); catalogued as rs370466913; called by muse, mutect2, varscan2
- PBRM1 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56304081, COSV56308416; called by muse, mutect2, varscan2
- PHF24 | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV54276921; called by muse, mutect2
- PHF24 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV54276933; called by muse, mutect2, varscan2
- PHF24 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as COSV54276944; called by muse, mutect2, varscan2
- PIGG | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752489514, COSV56321463; called by muse, mutect2, varscan2
- PIK3CD | c.339C>G p.I113M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV63131897; called by muse, mutect2, varscan2
- PIK3CG | c.3052C>G p.L1018V | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV63248005, COSV63252235; called by muse, mutect2, varscan2
- PKHD1 | c.4685C>T p.S1562F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61894765; called by muse, mutect2, varscan2
- PLCH2 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs765158941, COSV53949648; called by muse, mutect2, varscan2
- POLDIP3 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV52810321; called by muse, mutect2, varscan2
- POLR1A | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55699694; called by muse, mutect2, varscan2
- POLR3A | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs1554838298, COSV64932103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMGNT2 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV60954681; called by mutect2, varscan2
- POMK | c.1033C>A p.Q345K | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.038); catalogued as COSV58858607; called by muse, mutect2, varscan2
- POMT2 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV55073972; called by muse, mutect2, varscan2
- PPIL4 | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV53568792; called by muse, mutect2, varscan2
- PPM1B | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56769795; called by muse, mutect2, varscan2
- PRDM11 | c.874G>C p.E292Q (on ENST00000530656 / NM_001359633.1; = p.E258Q on NM_001256695.1) | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as COSV55443738; called by muse, mutect2, varscan2
- PRDM2 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs767849543, COSV52455617; called by muse, mutect2, varscan2
- PRDM4 | c.833A>T p.N278I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV57307620; called by muse, mutect2, varscan2
- PRRC2B | c.3182G>A p.R1061K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV61943033; called by muse, mutect2, varscan2
- PRSS21 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV50052300; called by muse, mutect2, varscan2
- PSMD5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.024); catalogued as COSV52962034; called by muse, mutect2, varscan2
- PTCH1 | c.2560G>A p.G854R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV59501164; called by muse, mutect2
- PTH2R | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV55920329; called by muse, mutect2, varscan2
- PURB | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV67480609; called by muse, mutect2, varscan2
- RAB3B | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63228436; called by muse, mutect2, varscan2
- RB1 | c.2339C>A p.S780* | Nonsense Mutation (SNP) | VAF 59/138 reads (43%) | catalogued as CM058003, COSV57316285; called by muse, mutect2, varscan2
- RBM43 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV58879723, COSV58879912; called by muse, mutect2
- REC8 | c.865-1G>C p.X289_splice | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100268953, COSV61018374; called by muse, mutect2, varscan2
- RIOK3 | c.445C>G p.P149A | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59775157; called by muse, mutect2, varscan2
- RNASE3 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs746822072, COSV58959386, COSV58959993; called by muse, mutect2, varscan2
- RNASEL | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV62377992; called by muse, mutect2, varscan2
- RNF10 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV100378488; called by muse, mutect2, varscan2
- RNF19A | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | catalogued as COSV61992867; called by muse, mutect2, varscan2
- RNF19A | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as rs772588450, COSV61994756; called by muse, mutect2, varscan2
- RNF213 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60630305; called by muse, mutect2, varscan2
- RNF216 | c.1681G>C p.E561Q (on ENST00000425013 / NM_207116.3; = p.E618Q on NM_207111.4) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV66292719; called by muse, mutect2, varscan2
- RNF217 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs754718844, COSV71376586; called by muse, mutect2, varscan2
- RP1 | c.1997C>T p.S666L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV55126783; called by muse, mutect2, varscan2
- RPL11 | c.43C>T p.R15C (on ENST00000374550 / NM_001199802.1; = p.R16C on NM_000975.5) | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV104424061, COSV65778940; called by muse, mutect2, varscan2
- RUSC2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63430425; called by muse, mutect2, varscan2
- RYBP | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV101523319; called by muse, mutect2, varscan2
- S100PBP | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV63140674; called by muse, mutect2, varscan2
- S100PBP | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63140266, COSV63140685; called by muse, varscan2
- SCP2 | c.219G>C p.Q73H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65262594; called by muse, mutect2, varscan2
- SCTR | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50031918; called by muse, mutect2, varscan2
- SEC23B | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 87/446 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV52723906; called by muse, mutect2, varscan2
- SEC23B | c.1234-1G>C p.X412_splice | Splice Site (SNP) | VAF 21/90 reads (23%) | catalogued as COSV52721863, COSV52723918; called by muse, mutect2, varscan2
- SEC31B | c.562C>G p.H188D | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV64825164; called by muse, mutect2, varscan2
- SERPINA10 | c.739G>C p.D247H | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56229720; called by muse, mutect2, varscan2
- SETD3 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as rs776504574, COSV59287144; called by muse, mutect2, varscan2
- SGK3 | c.582del p.I197* | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as COSV61896805; called by mutect2, pindel, varscan2
- SLC2A1 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as CM159224, COSV65288478; called by muse, mutect2
- SLCO1B1 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57017006; called by muse, mutect2, varscan2
- SMAD3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1429991069, COSV59287781; called by muse, mutect2, varscan2
- SMAD3 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs773543026, COSV59290098; called by muse, mutect2, varscan2
- SMG1 | c.6550G>A p.E2184K | Missense Mutation (SNP) | VAF 134/322 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV67174798; called by muse, mutect2, varscan2
- SNAPC2 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs772674180, COSV54494643; called by muse, mutect2, varscan2
- SOWAHC | c.1573G>C p.G525R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61782073; called by muse, mutect2, varscan2
- SPEG | c.4068C>G p.I1356M | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56679672; called by muse, mutect2, varscan2
- SPHKAP | c.4815G>C p.Q1605H (on ENST00000392056 / NM_001142644.2; = p.Q1576H on NM_030623.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV60894181; called by muse, mutect2
- SPRTN | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV50479800; called by muse, mutect2, varscan2
- SRCAP | c.7679C>G p.S2560C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as COSV52681123; called by muse, mutect2, varscan2
- SSBP4 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54212423; called by muse, mutect2, varscan2
- ST3GAL6 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as COSV54585053; called by muse, mutect2, varscan2
- SUPT20H | c.2307G>T p.M769I | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV53510098; called by muse, mutect2, varscan2
- TANGO6 | c.996G>A p.A332= | Splice Region (SNP) | VAF 22/83 reads (27%) | catalogued as rs373016239, COSV55772893; called by muse, mutect2, varscan2
- TBCEL | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV52462604; called by muse, mutect2, varscan2
- TCHH | c.5610G>C p.Q1870H | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV64277721; called by muse, mutect2, varscan2
- TCP11L2 | c.1366C>G p.Q456E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV54432583; called by muse, mutect2, varscan2
- TCP11L2 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV54432593; called by muse, varscan2
- TCTEX1D2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as COSV57488211, COSV57489713; called by muse, mutect2, varscan2
- TENT5B | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs777073358, COSV100006428, COSV56693088; called by muse, mutect2, varscan2
- TESPA1 | c.1217C>T p.P406L (on ENST00000316577 / NM_001098815.3; = p.P268L on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV57261530; called by muse, mutect2, varscan2
- THAP7 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 19/325 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV53147736; called by muse, mutect2
- THOC1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757641974, COSV55276654; called by muse, mutect2, varscan2
- TIAM1 | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54550195; called by muse, varscan2
- TIMM44 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV54492477; called by muse, mutect2, varscan2
- TNKS | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs772995748, COSV60066288; called by muse, mutect2, varscan2
- TNS2 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs754839630, COSV58582022; called by muse, mutect2, varscan2
- TOP2A | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867421081, COSV70733884; called by muse, mutect2, varscan2
- TP53 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TP53 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1131691007, COSV52713626, COSV52853816, COSV53387316, COSV53697288; ClinVar: uncertain significance; called by muse, varscan2
- TRAK1 | c.1380C>A p.D460E (on ENST00000327628 / NM_001349247.2; = p.D402E on NM_014965.5) | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.574); catalogued as COSV58264655; called by muse, mutect2, varscan2
- TRAPPC8 | c.2029G>T p.V677F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51977360; called by muse, mutect2, varscan2
- TRPM1 | c.3548G>T p.R1183L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV56642390; called by muse, mutect2, varscan2
- TRPM6 | c.3195G>C p.L1065F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62522361; called by muse, mutect2, varscan2
- TSHR | c.1383C>G p.F461L | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV53331612, COSV99992801; called by muse, mutect2, varscan2
- TTC3 | c.5290A>T p.T1764S | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs201341473, COSV61296251; called by muse, mutect2, varscan2
- TTN | c.100663G>A p.E33555K (on ENST00000591111; = p.E26131K on NM_003319.4) | Missense Mutation (SNP) | VAF 104/405 reads (26%) | PolyPhen possibly damaging (0.724); catalogued as COSV60347604; called by muse, mutect2, varscan2
- TTN | c.83175G>C p.K27725N (on ENST00000591111; = p.K20301N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | PolyPhen benign (0.206); catalogued as COSV59963635; called by muse, mutect2, varscan2
- TULP4 | c.4136G>A p.R1379K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.98); catalogued as COSV65580856; called by muse, mutect2, varscan2
- UBN1 | c.2268G>C p.E756D | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV52172925; called by muse, mutect2, varscan2
- UBN1 | c.3345G>C p.Q1115H | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1021261724, COSV52172934; called by muse, mutect2, varscan2
- USP47 | c.533C>G p.S178C (on ENST00000399455 / NM_001372095.1; = p.S90C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV60467971; called by muse, mutect2, varscan2
- VSIG10 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 25/186 reads (13%) | catalogued as rs1232220363; called by muse, mutect2, varscan2
- WASHC5 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59200561; called by muse, mutect2, varscan2
- YLPM1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53123514; called by muse, mutect2, varscan2
- YOD1 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV60007065; called by muse, mutect2, varscan2
- YOD1 | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as COSV60007080; called by muse, mutect2, varscan2
- ZBBX | c.1834C>A p.H612N | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV56801475; called by muse, mutect2, varscan2
- ZC3H14 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV51773632; called by muse, mutect2, varscan2
- ZC3H4 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV53413550; called by muse, mutect2, varscan2
- ZCCHC3 | c.1032G>C p.M344I | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV66643799; called by muse, mutect2, varscan2
- ZDHHC14 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV63077647; called by muse, mutect2, varscan2
- ZDHHC3 | c.766G>A p.E256K (on ENST00000424952 / NM_001135179.2; = p.E284K on NM_016598.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV56102607; called by muse, varscan2
- ZNF280B | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs775765845, COSV64528312, COSV64528706; called by muse, mutect2, varscan2
- ZNF385D | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs571099747, COSV55752958; called by muse, mutect2, varscan2
- ZNF585B | c.965G>C p.R322T | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV57217039; called by muse, mutect2, varscan2
- ZNF594 | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68386223; called by muse, mutect2, varscan2
- ZNF644 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61350381; called by muse, mutect2, varscan2
- ZNF749 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV61945945, COSV61948249; called by muse, mutect2, varscan2
- ZNF804A | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56435236; called by muse, mutect2
- ABCA2 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.9); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BTN3A3 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CDRT1 | c.17C>G p.S6* | Nonsense Mutation (SNP) | VAF 129/404 reads (32%) | called by muse, mutect2, varscan2
- DDX5 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- E2F3 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- EIF4A2 | c.789_790del p.C265* | Frame Shift Del (DEL) | VAF 42/208 reads (20%) | called by pindel, varscan2
- FAM111B | c.1949C>G p.S650* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- FBXO28 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FUT3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- GLTP | c.66_85del p.F23Pfs*129 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- HERC2P3 | n.1375G>C | Splice Region (SNP) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- IL21R | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- KDM6A | c.208_217del p.K70Wfs*11 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by pindel, varscan2
- KIFC1 | c.838del p.A280Qfs*4 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- KLHL11 | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- KRTAP9-8 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- NUB1 | c.1675C>A p.P559T (on ENST00000568733 / NM_001243351.1; = p.P545T on NM_016118.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.197); called by muse, mutect2
- PKHD1L1 | c.12049G>C p.E4017Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.642); called by muse, mutect2
- PTEN | c.853_862del p.E285Kfs*3 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- RANBP3 | c.398C>G p.S133* | Nonsense Mutation (SNP) | VAF 48/119 reads (40%) | called by muse, mutect2, varscan2
- RASD2 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- RSPRY1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- UROD | c.344_345del p.E115Afs*15 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by pindel, varscan2
- ABCC1 | c.549C>T p.L183= | Silent (SNP) | VAF 60/365 reads (16%) | catalogued as COSV60693965; called by muse, mutect2, varscan2
- ABHD8 | c.729G>A p.K243= | Silent (SNP) | VAF 40/217 reads (18%) | catalogued as COSV53113420; called by muse, mutect2, varscan2
- ACBD7 | c.246G>C p.L82= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV62252709; called by muse, mutect2, varscan2
- ADGRB1 | c.2580G>A p.P860= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs377353688, COSV60096316; called by muse, mutect2, varscan2
- AKT1S1 | c.654C>T p.I218= (on ENST00000344175 / NM_001098633.4; = p.I238= on NM_032375.5) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs766848323, COSV59273976; called by mutect2, varscan2
- ALDH16A1 | c.1323G>A p.L441= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53196697, COSV99512816; called by muse, mutect2, varscan2
- APLNR | c.918C>T p.P306= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV57244074; called by muse, mutect2, varscan2
- ARHGEF10 | c.3420C>G p.L1140= (on ENST00000398564; = p.L1115= on NM_014629.4) | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV50678073; called by muse, mutect2, varscan2
- ATP2B4 | c.3285G>A p.R1095= | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs1162721151, COSV58183850; called by muse, mutect2, varscan2
- BRCA1 | c.1026G>C p.L342= | Silent (SNP) | VAF 31/208 reads (15%) | catalogued as COSV58799539; called by muse, mutect2, varscan2
- CCNF | c.939G>A p.L313= | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV53543217; called by muse, mutect2, varscan2
- CCR8 | c.432G>A p.V144= | Silent (SNP) | VAF 71/292 reads (24%) | catalogued as COSV58338008; called by muse, varscan2
- CDK15 | c.1231C>T p.L411= (on ENST00000652192 / NM_001366386.2; = p.L360= on NM_139158.2) | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV53638471; called by muse, mutect2, varscan2
- CDK18 | c.168G>A p.Q56= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1320148507, COSV63728936; called by muse, mutect2
- COL13A1 | c.2133C>G p.V711= (on ENST00000398978 / NM_001130103.2; = p.V639= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV62575199; called by muse, mutect2, varscan2
- CYP4F8 | c.906C>T p.L302= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- DAGLB | c.717C>T p.L239= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs751467052, COSV51706478; called by muse, mutect2, varscan2
- DNAH5 | c.6624C>G p.L2208= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV54247917, COSV54252061; called by muse, mutect2
- DTNB | c.681C>T p.L227= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV56484674; called by muse, mutect2
- EHD2 | c.1158G>A p.L386= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV54410912; called by muse, mutect2, varscan2
- EIF4E2 | c.606A>G p.R202= | Silent (SNP) | VAF 57/240 reads (24%) | catalogued as COSV51473400; called by muse, mutect2, varscan2
- ELAPOR2 | c.813C>G p.V271= (on ENST00000450689 / NM_001142749.3; = p.V104= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV51891883; called by muse, mutect2, varscan2
- ELOVL5 | c.537C>T p.L179= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as COSV58653198; called by muse, mutect2, varscan2
- EMX1 | c.789G>A p.K263= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV50689690; called by muse, mutect2, varscan2
- EP400 | c.6120G>A p.P2040= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs997030576, COSV57786391; called by muse, mutect2, varscan2
- FAT3 | c.7827C>T p.V2609= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV53173653; called by muse, mutect2, varscan2
- FRG1 | c.753G>A p.L251= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV57007992; called by muse, mutect2, varscan2
- GALNT6 | c.801C>T p.F267= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- GAREM1 | c.42G>A p.V14= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52515995; called by muse, mutect2, varscan2
- GATC | c.189C>T p.F63= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV56664234; called by muse, mutect2, varscan2
- GID8 | c.339C>T p.I113= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56612313; called by muse, mutect2, varscan2
- GJB3 | c.642C>G p.V214= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV64904858; called by muse, mutect2, varscan2
- GPA33 | c.36C>G p.L12= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV54810096; called by muse, varscan2
- GRIK3 | c.1161G>A p.R387= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV66146780; called by muse, varscan2
- HHIPL2 | c.555G>A p.L185= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV58567901; called by muse, mutect2, varscan2
- HIRIP3 | c.987G>A p.L329= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as COSV54231757; called by muse, mutect2, varscan2
- HMGB2 | c.57C>T p.F19= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV56633223; called by muse, mutect2, varscan2
- IGDCC4 | c.2427C>A p.L809= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV61539252; called by muse, mutect2, varscan2
- IGLV7-46 | c.315T>A p.A105= | Silent (SNP) | VAF 73/116 reads (63%) | called by muse, mutect2, varscan2
- IGSF9B | c.2193C>T p.I731= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV58072802; called by muse, mutect2, varscan2
- KANK4 | c.2520G>A p.V840= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs532705606, COSV100443043, COSV58094116; called by muse, mutect2, varscan2
- KATNB1 | c.1623G>C p.L541= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV101109106, COSV65553226; called by muse, mutect2, varscan2
- KCNIP3 | c.465C>T p.L155= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54673101; called by muse, varscan2
- KMT2D | c.6813C>A p.P2271= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56486154; called by muse, mutect2, varscan2
- LENG9 | c.1080G>A p.L360= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1293601843, COSV56619906; called by muse, mutect2, varscan2
- LMAN1L | c.750C>T p.F250= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV59003733; called by muse, mutect2, varscan2
- LRRC37A2 | c.4854C>T p.F1618= | Silent (SNP) | VAF 26/224 reads (12%) | catalogued as rs775321707; called by muse, mutect2, varscan2
- MED24 | c.2403C>G p.L801= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV56641985; called by muse, mutect2, varscan2
- MFHAS1 | c.420C>T p.L140= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1209921936, COSV52286908; called by muse, mutect2, varscan2
- MTRES1 | c.510G>A p.L170= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as COSV60968859; called by muse, mutect2, varscan2
- MUC16 | c.40386G>C p.S13462= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs372905031, COSV66696463, COSV66697437; called by muse, mutect2
- MYO18A | c.5844C>T p.L1948= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV62873238; called by muse, mutect2, varscan2
- NECTIN1 | c.966C>T p.I322= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs774045034, COSV50608548; called by muse, mutect2, varscan2
- NECTIN4 | c.1077C>G p.L359= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV63514010; called by muse, mutect2, varscan2
- NOTCH4 | c.5250C>T p.A1750= | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as COSV66683758; called by muse, mutect2, varscan2
- NPTX2 | c.894G>T p.A298= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV55719347; called by muse, mutect2, varscan2
- NT5DC3 | c.687C>T p.C229= | Silent (SNP) | VAF 21/135 reads (16%) | catalogued as rs367719335; called by muse, mutect2, varscan2
- OR52B4 | c.867G>A p.L289= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV68769516; called by muse, mutect2, varscan2
- OR5A2 | c.105C>G p.L35= | Silent (SNP) | VAF 9/48 reads (19%) | called by mutect2, varscan2
- OR6C3 | c.186C>T p.N62= | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV65572108; called by muse, mutect2, varscan2
- PADI3 | c.150C>T p.I50= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV64935405; called by muse, mutect2, varscan2
- PARD3B | c.1461C>G p.L487= | Silent (SNP) | VAF 36/167 reads (22%) | catalogued as COSV62530589; called by muse, varscan2
- PCDH17 | c.1965G>A p.V655= | Silent (SNP) | VAF 68/197 reads (35%) | catalogued as COSV64979212; called by muse, mutect2, varscan2
- PDCL3 | c.495G>A p.T165= | Silent (SNP) | VAF 33/306 reads (11%) | catalogued as rs763038336, COSV51809001, COSV51810304; called by muse, mutect2, varscan2
- PDSS2 | c.177C>T p.I59= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1466717427, COSV100941804, COSV64650331; called by muse, mutect2, varscan2
- PISD | c.753C>G p.L251= (on ENST00000439502 / NM_001326412.1; = p.L217= on NM_014338.3) | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV56717849; called by muse, mutect2, varscan2
- PLAAT4 | c.162G>A p.L54= | Silent (SNP) | VAF 35/216 reads (16%) | catalogued as rs367717733; called by muse, mutect2, varscan2
- PMEL | c.712C>T p.L238= | Silent (SNP) | VAF 48/189 reads (25%) | catalogued as rs779993487, COSV59388691; called by muse, mutect2
- PPL | c.4681C>T p.L1561= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs372524698; called by muse, mutect2, varscan2
- PRDX2 | c.153C>T p.C51= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV56878824; called by muse, mutect2, varscan2
- PRPF3 | c.843G>C p.L281= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV61396424; called by muse, mutect2, varscan2
- PRUNE2 | c.6363C>T p.L2121= | Silent (SNP) | VAF 63/159 reads (40%) | catalogued as COSV65047950; called by muse, mutect2, varscan2
- PSMD2 | c.2577G>A p.P859= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs754936889, COSV59529697; called by muse, mutect2, varscan2
- PTPRJ | c.3648C>T p.I1216= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs2229704; called by muse, mutect2, varscan2
- R3HDML | c.306C>T p.T102= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV53837729; called by muse, mutect2, varscan2
- RECK | c.2370C>T p.V790= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs769082755, COSV65036339; called by muse, mutect2, varscan2
- RIMBP2 | c.2145C>T p.F715= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV55484307; called by muse, mutect2
- RYR2 | c.12012G>A p.V4004= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV63713474; called by mutect2, varscan2
- SFTPA1 | c.594C>T p.F198= | Silent (SNP) | VAF 87/195 reads (45%) | catalogued as COSV64867745; called by muse, mutect2, varscan2
- SHC3 | c.909C>G p.L303= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV65440777; called by muse, mutect2
- SHLD2 | c.2130G>A p.E710= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- SLC38A2 | c.369G>A p.L123= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as rs61761952, COSV56746471; called by muse, mutect2, varscan2
- SLC5A4 | c.1119G>C p.L373= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV56671459; called by muse, mutect2, varscan2
- SLC9A8 | c.1371C>T p.L457= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as rs756534105, COSV64291371; called by muse, mutect2, varscan2
- SPATS2L | c.703C>T p.L235= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV62349172, COSV62352934; called by muse, mutect2, varscan2
- SPECC1L | c.2925G>A p.Q975= | Silent (SNP) | VAF 42/231 reads (18%) | catalogued as COSV58662050; called by muse, mutect2, varscan2
- SPHKAP | c.3360G>C p.S1120= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100764506, COSV60878017, COSV60894188; called by muse, mutect2, varscan2
- SRP72 | c.1857G>C p.V619= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV61379313; called by muse, mutect2, varscan2
- SSBP3 | c.1166G>A p.*389= (on ENST00000371320 / NM_145716.4; = p.*369= on NM_018070.5) | Silent (SNP) | VAF 64/288 reads (22%) | called by muse, mutect2, varscan2
- TAS2R31 | c.144C>G p.L48= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV66831250; called by muse, mutect2, varscan2
- TBC1D2B | c.411G>A p.K137= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV56046215, COSV56046298; called by muse, mutect2, varscan2
- TIAM1 | c.3465C>A p.V1155= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54574467; called by muse, varscan2
- TIMM23 | c.57C>T p.F19= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs782199630; called by muse, mutect2, varscan2
- TMC1 | c.606C>T p.L202= | Silent (SNP) | VAF 67/165 reads (41%) | catalogued as COSV52785352; called by muse, mutect2, varscan2
- TMEM177 | c.654C>T p.F218= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV55609674; called by muse, mutect2, varscan2
- TOPBP1 | c.699G>A p.L233= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV53441642; called by muse, mutect2, varscan2
- TOR2A | c.405C>T p.I135= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV59129587; called by muse, mutect2, varscan2
- TRHDE | c.210G>C p.A70= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs749621897; called by muse, mutect2
- TTBK1 | c.2805G>A p.E935= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV52496554; called by muse, mutect2, varscan2
- UBN1 | c.1896G>C p.L632= | Silent (SNP) | VAF 24/137 reads (18%) | catalogued as COSV52172910; called by muse, mutect2, varscan2
- UNC93A | c.408G>A p.Q136= | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV57810961; called by muse, mutect2, varscan2
- VILL | c.1197G>A p.Q399= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV52187905; called by muse, mutect2, varscan2
- VILL | c.1308G>T p.L436= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV52187917; called by muse, mutect2, varscan2
- VILL | c.1416G>A p.V472= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as rs1253974191, COSV52187935; called by muse, mutect2, varscan2
- VSIG8 | c.495G>T p.L165= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV63652654, COSV63653562; called by muse, mutect2, varscan2
- WDR90 | c.4680C>T p.F1560= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV53475244; called by muse, mutect2, varscan2
- WRN | c.3975C>T p.V1325= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV53307366; called by muse, mutect2, varscan2
- ZDHHC14 | c.210C>T p.L70= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs757317453, COSV63077645; called by muse, mutect2, varscan2
- ZFAT | c.3276C>G p.L1092= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as COSV64736384, COSV64747122; called by muse, mutect2
- ZNF136 | c.84C>G p.L28= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV59711833; called by muse, mutect2, varscan2
- ZNF599 | c.876C>T p.F292= | Silent (SNP) | VAF 47/166 reads (28%) | catalogued as COSV61397461; called by muse, mutect2, varscan2
- ATAD3B | c.325-88G>A | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ATP6V0E2 | c.*322C>A | 3'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as COSV70416789, COSV70416891; called by mutect2, varscan2
- ETNK1 | c.416+265C>T | Intron (SNP) | VAF 10/43 reads (23%) | catalogued as COSV56889820; called by muse, mutect2, varscan2
- HNMT | c.190+11004C>G | Intron (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99699134; called by muse, mutect2
- NHLRC3 | c.-2T>C | 5'UTR (SNP) | VAF 8/125 reads (6%) | catalogued as rs1439624120, COSV100613060; called by muse, mutect2
- PPP3CA | c.58+16350C>G | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as rs1219448318, COSV100548065; called by muse, mutect2
- PPP4R4 | c.295-3258C>T | Intron (SNP) | VAF 25/96 reads (26%) | catalogued as COSV58558315; called by muse, mutect2, varscan2
- PRDM15 | c.-381C>T | 5'UTR (SNP) | VAF 29/98 reads (30%) | catalogued as rs374855659; called by muse, mutect2, varscan2
- PRMT2 | c.654+2252C>T | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as COSV52457908; called by muse, mutect2, varscan2
- ROPN1B | c.-2C>T | 5'UTR (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99305697; called by muse, mutect2, varscan2
- TSC22D1 | c.2913-423G>A | Intron (SNP) | VAF 61/138 reads (44%) | catalogued as COSV54926566; called by muse, mutect2, varscan2
- VTCN1 | c.98-72C>T | Intron (SNP) | VAF 16/53 reads (30%) | catalogued as rs1301229655, COSV100062325; called by muse, mutect2, varscan2
- ZNF658B | n.1302C>G | RNA (SNP) | VAF 63/205 reads (31%) | catalogued as rs1397446308; called by muse, mutect2, varscan2
